Gene-level copy-number profile of tumor specimen TCGA-06-0686-01A from TCGA case TCGA-06-0686, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,503 days).
Specimen TCGA-06-0686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.721d99cf-3581-4aab-9e18-90d8ce1a9f2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0686-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb0c2703-e6e8-4952-a4cb-2c87b359da72

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,029; copy number 3: 12,702; copy number 4: 37,722; copy number 5: 3,186; copy number 6: 20; copy number 7: 2,999; copy number 10: 15; copy number 16: 29; copy number 17: 7; copy number 19: 28; copy number 21: 10; copy number 23: 7; copy number 26: 17; copy number 28: 4; copy number 30: 6; copy number 34: 6; copy number 45: 2; copy number 48: 11; copy number 56: 9; copy number 57: 8; copy number 61: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0686-01A-01D-0333-01): tumor purity 0.85, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 160 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:43,576,185–43,687,791, 6 genes, copy number 21 (within-gene range 2–21): POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A.
- chr6:43,722,786–44,830,188, 31 genes, copy number 16–48 (within-gene range 2–48): AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1.
- chr6:45,328,157–45,664,349, 1 gene, copy number 26 (within-gene range 2–26): RUNX2.
- chr6:45,573,346–45,576,770, 1 gene, copy number 26: RUNX2-AS1.
- chr6:47,477,789–47,627,263, 2 genes, copy number 45 (within-gene range 2–45): CD2AP, AL358178.1.
- chr6:47,781,982–48,214,794, 6 genes, copy number 34: OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:48,754,649–48,795,513, 1 gene, copy number 30: AL391538.1.
- chr7:54,556,970–55,344,958, 15 genes, copy number 10 (within-gene range 7–10): VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr12:57,089,043–57,760,411, 43 genes, copy number 16–26: NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9.
- chr12:62,643,994–62,935,150, 1 gene, copy number 17 (within-gene range 2–39): PPM1H.
- chr12:62,850,738–63,360,037, 11 genes, copy number 17–61: RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:66,023,620–66,254,622, 9 genes, copy number 19 (within-gene range 2–19): MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3.
- chr12:67,424,272–67,590,771, 4 genes, copy number 21: NTAN1P3, LINC02420, LINC02408, LINC02442.
- chr12:67,989,445–68,234,686, 5 genes, copy number 30 (within-gene range 2–30): IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,248,242–68,687,755, 15 genes, copy number 23–57: IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42.
- chr12:68,805,011–68,971,570, 9 genes, copy number 56: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
